Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A76R, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A76R-01A (Primary Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology Document State: (version)
Update Date/Time:
Final 1

Patient Name: MRN:
DOB/Age/Gender: Male Provider:
Location: Responsible Staff:

Service Date/Time:

ICD-O-3
Oligodendroglioma, grade III
9451/13
Site: Cerebrum, supratentorial NOS
C71.0
path Overlapping lesion of brain
(temporoparietal) C71.8
9/13/13

Surgical Pathology Report

Patient Name:

Med: Rec.:

DOB:

Client:

Taken:

Received:

Reported:

Physician(s):

Phy Location:

Accession #:

Phone Number:

Gender: M

Location:

CLINICAL HISTORY

year old man has had mental status change and
on
imaging has a right temporoparietal, partially cystic, and with calcification
large tumor.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, biopsy

B: Brain, resection, perm

PATHOLOGICAL DIAGNOSIS:

A. Brain, site not specified, resection: Oligodendroglioma.

B. Brain, site not specified, resection: Oligodendroglioma with focal
anaplastic transformation.

See comment.

COMMENT

Parts A and B are portions of cerebrum extensively infiltrated and focally
effaced by a glial neoplastic proliferation with an oligodendroglial
phenotype. The neoplasm has the morphology of a "looser" tumor. In part A
there are no features of atypia. In part B there is on focal area with brisk
mitotic activity, focal microvascular cellular proliferation, conspicuous
tumor cell and microvessel karyorrhexis, and focal tumor necrosis, i. e.
anaplastic transformation (WHO grade III).

Special stains to better characterize the neoplasm are being requested and
will be reported as an addendum.

Electronically Signed Out

Senior Staff Pathologist

PROCEDURES/ADDENDA

Addendum

Date Ordered:

Date Reported:

Addendum Diagnosis

Brain, immunohistochemistry: MIB-1 proliferation index: \R\ 10%.

See comment.

Addendum Comment

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates sparse gliofibrillary background,

[page 2 of 2]
with small focal areas with heavier glial processes. The neoplastic cells do not over express the p53 protein. With the MIB-1 a proliferation index of 8% to 10% is determined in the more active areas.

Comment: The immunophenotype supports the diagnosis of high histological grade oligodendroglioma.

Electronically Signed Out

Senior Staff Pathologist

=====

INTRA-OPERATIVE CONSULTATION

Brain, touch prep and smears: Glioma (C/W oligodendroglioma. Neurocytoma???).

Senior Staff Pathologist

GROSS DESCRIPTION

A.

Received fresh, several fragments, 2.7 cm. across in aggregate. Semifirm, tannish-pink, focally firm and yellowish. In total, A1-A3.

B.

In formalin, several fragments, 3.5 cm. across in aggregate. Semi-firm, pinkish-yellow, focally hemorrhagic. In total, B1 and B2.

ICD-9(s):

742.4 742.4

Billing Fee Code(s):

A:

B:

Histo Data

Part A: Brain, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H/E x 1 1

mGFAP-DA x 1 2

H/E x 1 2

MIB1-DA x 1 2

P53DO7 x 1 2

H/E x 1 3

Part B: Brain, resection, perm

Taken: Received:

Stain/cnt Block Ordered Comment

mGFAP-DA x 1 1

H/E x 1 1

MIB1-DA x 1 1

P53DO7 x 1 1

H/E x 1 2

*** End of Report ***

LiPAA Discrepancy		✓

Source: NCI Genomic Data Commons file ae64a6a1-3ec7-4329-a2d8-91761df135af (TCGA-DU-A76R.7D334156-3FCB-4C90-AD99-60778721193D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).